Somatic mutation profile of tumor specimen 0DFXH1 from CCDI case PBBSCI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.8 years (2,851 days).
Specimen 0DFXH1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3421e97e-d442-459b-9729-6a07174fac28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXEX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d0e1d17-505e-426d-b272-ae5081c7ec57

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYSRT1 | c.239C>T p.S80L (on ENST00000409414; = p.S40L on NM_199001.5) | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1361497570, COSV100763202; called by muse, mutect2
- ENPEP | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 229/620 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs200528408, COSV54449792; called by muse, mutect2, varscan2
- RHBDD1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 382/1087 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773433822, COSV58125871; called by muse, mutect2, varscan2
